Surgical pathology report (de-identified scan), TCGA case TCGA-78-8648, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-8648-01A (Primary Tumor).

[page 1 of 2]
HISTORY

Histopathology of right upper lobe and chest wall resection for cancer

MACROSCOPIC

Three specimens received.

1: The specimen is labelled "right upper lobe" and consists of a right upper lobe with attached chest wall. The right upper lobe measures 140 x 100 x 79 mm in maximum dimension. The chest wall component consists of four ribs and measures 140 x 60 mm in maximum dimension. On the hilar surface there are two vertical soft tissue excision margins which are closed with staples, the longest of which measures 90 mm and the other measures 60 mm. The staples are removed and the new resection margin is inked in blue. On sectioning the specimen there is a large cavitating mass which has an ill-defined lobulated appearance and measures, in maximum dimension, 58 x 55 mm. The tumour appears to lie approximately 13 mm from the bronchial resection margin. The tumour lies well clear of the longest soft tissue excision margin and approximately 8 mm from the shorter soft tissue excision margin. The chest wall is blunt dissected off the main specimen. The tumour does not appear macroscopically to have infiltrated the chest wall as there is a thickened greyish-white soft fibrous-like capsule between the tumour and the chest wall. The tumour focally appears to be very close to the serosal surface. The small amount of normal lung parenchyma that is present appears unremarkable. [1A, bronchial resection margin; 1B, hilar lymph nodes; 1C-D, tumour with nearest anterior chest wall; 1C-H, full TS of the tumour; 1I, tumour with nearest pleural surface; 1J, tumour with adjacent bronchus; 1K, ? fibrous capsule adjacent to anterior chest wall; 1L, normal lung parenchyma]. Please note the chest wall is submitted for decalcification and a further report will be issued upon examination of the ribs histologically.

2: The specimen is labelled "hilar lymph node" and consists of three irregular greyish-brown pieces of tissue measuring in aggregate 20 x 10 x 7 mm. [The largest is bisected and BIT with the other pieces, 2A].

3: The specimen is labelled "peri-oesophageal lymph node" and consists of an irregular piece of fibrofatty tissue measuring 15 x 7 x 4 mm. [Bisected and BIT, 3A].

MICROSCOPIC

1: Sections show a cavitated poorly differentiated adenocarcinoma. Also focally lining the cavity is a small amount of atypical squamous epithelium but a significant malignant squamous component is not identified within the carcinoma. The lesion is invading through visceral pleural to involve chest wall fibrous connective tissue. There is blood vessel invasion but no lymphatic permeation is seen. No perineural permeation is identified. The

[page 2 of 2]
lesion is well clear of the bronchial resection margin. No lymph node metastases are seen. Surrounding the tumour there is evidence of obstructive pneumonitis. The adjacent lung shows evidence of emphysema.

2: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

3: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

SUMMARY

Right upper lobe lung and lymph nodes:

- 1: Cavitated poorly differentiated adenocarcinoma; 58 mm in maximal dimension.
- 2: Blood vessel permeation identified but no lymphatic or perineural invasion present.
- 3: Visceral pleural invasion with chest wall involvement identified; clear of bronchial margin.
- 4: No lymph node metastases.
- 5: T3N0MX

COMMENT

A further report will be issued upon review of the chest wall and ribs.

SUPPLEMENTARY REPORT

Sections of the ribs and chest wall have been examined. [Rib resection margin one end, 1M; cartilage resection margin same end, 1N; rib and soft tissue resection margin other end, 1O; middle section of chest wall including the ribs as a full TS, 1P-1Q.]

There is no residual malignancy within the chest wall tissues and there is no involvement of rib bone. Three small chest wall lymph nodes are also present and these also show no evidence of malignancy. There is haemopoietic marrow within the rib bone.

SUMMARY

Right upper lobe: Poorly differentiated adenocarcinoma invading into chest wall but not involving rib bone or soft tissue resection margin.

Source: NCI Genomic Data Commons file aaf4e6de-ddcc-4d6f-a9bf-bcc737e28c4b (TCGA-78-8648.A439594E-B536-4BD3-A77A-FB50304DE9A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).